Somatic mutation profile of tumor specimen TCGA-G3-AAV3-01A (aliquot TCGA-G3-AAV3-01A-11D-A36X-10) from TCGA case TCGA-G3-AAV3, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 58.7 years (21,449 days).
Specimen TCGA-G3-AAV3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34760016-dd51-47cb-821a-f452968c2143.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-AAV3-10A (Blood Derived Normal), aliquot TCGA-G3-AAV3-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32610f31-7b91-477b-ab04-0c4c100a09c0

The open-access MAF lists 91 somatic variants for this specimen: 75 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 15, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 3, Splice Site 2, In Frame Del 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 42/144 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- NFE2L2 | c.242G>C p.G81A | Missense Mutation (SNP) | VAF 16/68 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960014, COSV67960167, COSV67960618; called by muse, mutect2, varscan2
- AC244197.3 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100558033; called by muse, mutect2, varscan2
- ACAD8 | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.298); catalogued as COSV99844381; called by muse, mutect2, varscan2
- AMPH | c.959T>A p.I320N | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100342366; called by muse, mutect2
- ART4 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as rs912581204, COSV57452138; called by muse, mutect2
- ATIC | c.889A>T p.T297S | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.006); catalogued as COSV99377850; called by muse, mutect2, varscan2
- BDP1 | c.2823A>T p.K941N | Missense Mutation (SNP) | VAF 38/200 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100703184; called by muse, mutect2, varscan2
- BMS1 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as COSV100996723; called by muse, mutect2, varscan2
- BRD7 | c.1337A>G p.H446R | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.053); catalogued as rs539023856, COSV101164972; called by muse, mutect2, varscan2
- CARMIL1 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 15/98 reads (15%) | catalogued as rs79463028, COSV61515476; called by muse, mutect2, varscan2
- CCDC7 | c.231dup p.L78Tfs*5 | Frame Shift Ins (INS) | VAF 43/178 reads (24%) | catalogued as rs1275671890, COSV53227152; called by mutect2, pindel, varscan2
- CEACAM18 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.031); catalogued as rs775191087, COSV67282189; called by muse, mutect2, varscan2
- CMTR1 | c.330C>A p.S110R | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV100990877; called by muse, mutect2, varscan2
- CMTR2 | c.1103A>G p.H368R | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as COSV100579190; called by muse, mutect2, varscan2
- CNOT1 | c.6671C>A p.T2224N | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV99800366; called by muse, mutect2, varscan2
- COL20A1 | c.2484G>T p.Q828H | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100490673; called by muse, mutect2
- CPZ | c.592A>T p.R198W (on ENST00000360986 / NM_001014447.3; = p.R187W on NM_003652.3) | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV100249007; called by muse, mutect2, varscan2
- CREB3L3 | c.976-2A>T p.X326_splice | Splice Site (SNP) | VAF 24/71 reads (34%) | catalogued as COSV99313995, COSV99314206; called by muse, mutect2, varscan2
- DENND4C | c.1612T>G p.S538A | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.88); PolyPhen benign (0.275); catalogued as rs1188202841, COSV100991363; called by muse, mutect2, varscan2
- ENO3 | c.1046C>A p.S349* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV99236567; called by muse, mutect2, varscan2
- FASN | c.4216C>T p.P1406S | Missense Mutation (SNP) | VAF 51/169 reads (30%) | SIFT tolerated (0.75); PolyPhen benign (0.035); catalogued as rs1310780026, COSV100147876; called by muse, mutect2, varscan2
- GABPB2 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100927238; called by muse, mutect2, varscan2
- GNB5 | c.1127C>T p.S376F (on ENST00000261837 / NM_016194.4; = p.S334F on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99953408; called by muse, mutect2, varscan2
- H3C11 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as rs747419710, COSV58899597; called by muse, mutect2, varscan2
- HADHB | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV100502030; called by muse, mutect2, varscan2
- HAGHL | c.105+1G>T p.X35_splice | Splice Site (SNP) | VAF 27/97 reads (28%) | catalogued as rs761851848, COSV99284897; called by muse, mutect2, varscan2
- HHAT | c.892G>T p.V298L | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as COSV99804671; called by muse, mutect2, varscan2
- IGFBP5 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV99288956; called by muse, mutect2, varscan2
- LAMA4 | c.5431G>A p.V1811I (on ENST00000230538 / NM_001105206.3; = p.V1804I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100038565; called by muse, mutect2, varscan2
- LIMA1 | c.1205G>T p.R402L | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100372477; called by muse, mutect2, varscan2
- LRP1B | c.4510A>G p.S1504G | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV101257730; called by muse, mutect2, varscan2
- LRRN1 | c.804A>C p.L268F | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100076358; called by muse, mutect2, varscan2
- MAGEE1 | c.1332C>A p.D444E | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100819414; called by muse, mutect2, varscan2
- MED13L | c.1780A>T p.T594S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99929021; called by muse, mutect2, varscan2
- NCOR2 | c.3761G>A p.R1254H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100657403; called by mutect2, varscan2
- NDUFA7 | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100035545; called by muse, mutect2, varscan2
- NPEPL1 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1430790801, COSV100622442; called by muse, mutect2, varscan2
- NR1H3 | c.185A>T p.E62V | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101269774; called by muse, mutect2, varscan2
- NRCAM | c.163G>C p.D55H (on ENST00000379028 / NM_001371124.1; = p.D49H on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100694809; called by muse, mutect2, varscan2
- NTRK3 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100446728, COSV58111355; called by muse, mutect2, varscan2
- OR2T4 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 147/702 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as COSV100822504; called by muse, mutect2, varscan2
- OSBPL1A | c.1225A>T p.R409* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as rs1225134138, COSV100111924; called by muse, mutect2, varscan2
- PCDHA13 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56505482; called by muse, mutect2, varscan2
- PER2 | c.317A>T p.D106V | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.397); catalogued as COSV99612055; called by muse, mutect2, varscan2
- PGBD2 | c.1561G>T p.A521S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100252071; called by muse, mutect2, varscan2
- PIGM | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs1163274966, COSV100928046; called by muse, mutect2, varscan2
- PKP3 | c.2392T>A p.*798Kext*? | Nonstop Mutation (SNP) | VAF 27/131 reads (21%) | catalogued as COSV100230093, COSV58987726; called by muse, mutect2, varscan2
- PLA1A | c.545A>T p.Q182L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.255); catalogued as COSV99845902; called by muse, mutect2, varscan2
- PLEKHG1 | c.1050C>G p.I350M | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100651684; called by muse, mutect2, varscan2
- PRKCQ | c.1508G>T p.R503M | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99577056; called by muse, mutect2, varscan2
- PRKG2 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV100019953; called by muse, mutect2, varscan2
- RASA3 | c.677T>A p.I226N | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100480666; called by muse, mutect2, varscan2
- RO60 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 79/396 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); catalogued as COSV100814395; called by muse, mutect2, varscan2
- RPH3A | c.581C>A p.P194H (on ENST00000389385 / NM_001143854.2; = p.P190H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV101231832; called by muse, mutect2, varscan2
- SAMD9 | c.264G>T p.M88I | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV101180273; called by muse, mutect2, varscan2
- SLC25A21 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV100491406; called by muse, mutect2, varscan2
- SLTM | c.1275A>T p.K425N | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV51055340, COSV99989201; called by muse, mutect2, varscan2
- SORL1 | c.5131A>T p.K1711* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV99494129; called by mutect2, varscan2
- STXBP1 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV100964583; called by mutect2, varscan2
- SV2B | c.1755dup p.G586Wfs*4 | Frame Shift Ins (INS) | VAF 9/62 reads (15%) | catalogued as rs1567438858; called by mutect2, pindel, varscan2
- TNKS2 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100861105; called by muse, mutect2, varscan2
- TPO | c.633T>A p.H211Q | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100221316; called by muse, mutect2, varscan2
- TPO | c.634G>T p.V212F | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100221320; called by muse, mutect2, varscan2
- UBQLNL | c.382A>T p.T128S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.202); catalogued as COSV100974514; called by muse, mutect2, varscan2
- WDR47 | c.1409A>G p.N470S (on ENST00000369962 / NM_001142551.2; = p.N471S on NM_014969.5) | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV100728369; called by muse, mutect2
- WNK1 | c.887G>A p.C296Y | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as COSV100267582; called by muse, mutect2, varscan2
- XIRP2 | c.9511T>A p.S3171T (on ENST00000628543; = p.S3346T on NM_152381.6) | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99743583; called by muse, mutect2, varscan2
- ZNF207 | c.496G>A p.G166S | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.437); catalogued as COSV100340534; called by muse, mutect2, varscan2
- AP2B1 | c.2280T>A p.N760K | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BACH1 | c.977del p.L326Yfs*10 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | called by mutect2, pindel, varscan2
- LAMB2 | c.2592_2615del p.Q865_P872del | In Frame Del (DEL) | VAF 42/216 reads (19%) | called by mutect2, pindel
- RPS9 | c.497_500dup p.R169Wfs*? | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- TNS3 | c.665del p.N222Tfs*15 | Frame Shift Del (DEL) | VAF 23/120 reads (19%) | called by mutect2, pindel, varscan2
- ZCCHC8 | c.229_230del p.L77Dfs*12 | Frame Shift Del (DEL) | VAF 23/111 reads (21%) | called by mutect2, pindel, varscan2
- CCDC170 | c.1098C>A p.V366= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs939373567, COSV99498498; called by muse, mutect2, varscan2
- CFAP54 | c.6555C>A p.G2185= | Silent (SNP) | VAF 59/308 reads (19%) | catalogued as COSV100733204; called by muse, mutect2, varscan2
- CLUH | c.604C>T p.L202= (on ENST00000435359; = p.L240= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs1353493911, COSV101425763; called by muse, mutect2, varscan2
- CPED1 | c.336T>C p.L112= | Silent (SNP) | VAF 44/225 reads (20%) | catalogued as COSV100120869; called by muse, mutect2, varscan2
- DNAH10 | c.8025C>A p.T2675= (on ENST00000409039; = p.T2614= on NM_207437.3) | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV101292315; called by muse, mutect2, varscan2
- EPHX1 | c.789C>T p.L263= | Silent (SNP) | VAF 65/163 reads (40%) | catalogued as COSV99689008; called by muse, mutect2, varscan2
- FMNL1 | c.2265C>T p.F755= | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as rs1375824695, COSV58957726; called by muse, mutect2
- GRIA3 | c.435G>A p.L145= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV52055991; called by muse, mutect2, varscan2
- RXYLT1 | c.948G>A p.K316= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV99706949; called by muse, mutect2, varscan2
- SLC2A2 | c.273A>G p.Q91= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as rs1163149975, COSV100049360; called by muse, mutect2, varscan2
- SMCHD1 | c.3906T>A p.L1302= | Silent (SNP) | VAF 53/253 reads (21%) | catalogued as COSV99861826; called by muse, mutect2, varscan2
- STK11IP | c.357C>T p.P119= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV99822915; called by muse, mutect2, varscan2
- TCTN1 | c.609T>C p.T203= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100886050; called by muse, mutect2, varscan2
- TUBB4A | c.354C>T p.D118= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs748051542, COSV51152652; called by muse, mutect2, varscan2
- VPS33A | c.747C>G p.L249= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as COSV99931400; called by muse, mutect2, varscan2
- USH1C | c.1285-3879T>C | Intron (SNP) | VAF 27/115 reads (23%) | catalogued as COSV99140239; called by muse, mutect2, varscan2
